Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5435, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5435-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

- (A) LEFT PYRIFORM SINUS:
DEEPLY INVASIVE SQUAMOUS CELL CARCINOMA.
Squamous mucosa with dysplasia.
- (B) RIGHT POSTERIOR NECK DISSECTION, LEVELS 2, 3 AND 4:
Thirty-six lymph nodes, no tumor present (Level 2, 0/20; Level 3, 0/9; Level 4, 0/7).
- (C) ESOPHAGEAL MARGIN:
Squamous mucosa, no tumor present.
- (D) TOTAL LARYNGOPHARYNGECTOMY, BILATERAL NECK DISSECTION AND SUBTOTAL THYROIDECTOMY:
INVASIVE MODERATELY TO POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH NECROSIS.
Margins of resection, free of tumor.
BILATERAL NECK DISSECTION, FIVE OF 42 LYMPH NODES WITH METASTATIC SQUAMOUS CELL CARCINOMA
(Right level II, six lymph nodes, no tumor present (0/6); Right level III, no lymph nodes present; Midline neck, two lymph nodes, no tumor present (0/2); Left level II, four lymph nodes, one with metastatic squamous cell carcinoma (1/4); Left level III, 18 lymph nodes, two with metastatic squamous cell carcinoma (2/18); Left level IV, 12 lymph nodes, two with metastatic squamous cell carcinoma (2/12)). (SEE COMMENT)
Right vocal cord, no tumor present.
Bilateral submandibular glands, no tumor present.
Left thyroid lobe, no tumor present.
- (E) CLOSEST LEFT OROPHARYNGEAL MARGIN:
Squamous mucosa with dysplasia and underlying lymphoid aggregate, no tumor present.

COMMENT

The squamous cell carcinoma in specimen D measures 5.0 x 4.5 cm and invades (1.8 cm) into the surrounding soft tissue, salivary glands and skeletal muscle. The tumor extension into the soft tissue may represent carcinoma metastatic in lymph nodes with marked extranodal extension and subsequent destruction of lymph node architecture.

GROSS DESCRIPTION

- (A) LEFT PYRIFORM SINUS - Multiple irregular mucosal fragments (0.3-0.6 cm), entirely frozen in A for intraoperative consultation.
*FS/DX: SQUAMOUS CARCINOMA.
- (B) RIGHT POSTERIOR NECK DISSECTION LEVELS 2, 3 AND 4 - Fibrofatty tissue 8.0

[page 2 of 2]
x 4.0 x 3.0 cm. Specimen oriented by Dr. [REDACTED] Multiple lymph nodes are recovered from each level which range in size from 0.1 cm to 1.1 cm in greatest dimension respectively.

SECTION CODE: B1-B4, level 2 lymph nodes; B5, B6, multiple lymph nodes from level 3; B7 and B8, multiple lymph nodes from level 4. [REDACTED]

(C) ESOPHAGEAL MARGIN - A 2.5 cm segment of esophagus marked with a clamp opposite the true margin. The margin is frozen en face for intraoperative consultation in C. [REDACTED]

*FS/DX: NO CARCINOMA IDENTIFIED. [REDACTED]

(D) TOTAL LARYNGOPHARYNGECTOMY, BILATERAL NECK DISSECTION AND SUBTOTAL THYROIDECTOMY - Specimen of portion of pharynx, larynx and proximal trachea (9.5 x 7.0 x 6.5 cm) with bilateral salivary glands and neck dissections, with prominent left neck dissection contents and left thyroid (4.0 x 1.5 x 1.0 cm). There is a 5.0 x 4.5 cm ulcerating tumor which is present in the left pyriform sinus and left hypopharynx extending to the supraglottic larynx just above the left false vocal cord. The tumor does not cross the midline. The tumor depth is 1.4 cm and abuts the bone. The tumor also extends into the retropharyngeal free space.

The right side of the larynx and the trachea appear otherwise unremarkable. Few smaller surface lesions identified on the left side of specimen which may be earlier precursor lesions. Multiple lymph nodes are recovered from the left neck dissection. The levels of the left neck has a large lymph node 2.5 x 1.5 x 1.5 cm, tan-white, firm.

There are very few lymph nodes on the right neck dissection (right neck contents sent as a separate specimen). Both salivary glands appear unremarkable, the thyroid appears unremarkable.

SECTION CODE: D1-D6, frozen section from 9 o'clock to 7 o'clock in a clockwise fashion (7 to 9 o'clock, left oropharyngeal margin has been sent as a separate specimen for frozen section); D7-D26, tumor submitted from medial to lateral sequentially; D27, right vocal cord representative; D28, left lobe of thyroid representative; D29, right submandibular gland representative; D30, D31, right Level II lymph node, one each; D32, two probable right Level II nodes; D33, one right Level II lymph node; D34, two right Level II lymph nodes; D35, one right Level III lymph node; D36, midline neck tissue containing probable lymph nodes; D37, left submandibular gland representative; D38-D41, one left Level II lymph node in each; D42-D45, multiple left Level III lymph node; D46-D49, multiple left Level IV lymph nodes. [REDACTED]

*FS/DX: NO CARCINOMA IDENTIFIED. [REDACTED]

(E) CLOSEST LEFT OROPHARYNGEAL MARGIN - Strip of mucosa 3.5 cm length with underlying soft tissue with clamps to orient. Surface opposite the clamps is a true margin which is inked in blue. Specimen bisected and submitted in E1 and E2 for frozen section. [REDACTED]

*FS/DX: CLOSEST LEFT OROPHARYNGEAL MARGIN, NO CARCINOMA IDENTIFIED. LYMPHOEPITHELIAL AGGREGATE (TONSILLAR TISSUE CLINICAL). [REDACTED]

SNOMED CODES

M-00110 M-80703 M-80706 T-24100 T-55320 T-56000 T-B6000 T-C4200

Source: NCI Genomic Data Commons file eeb97a03-9436-4059-97d2-839f342ab093 (TCGA-CV-5435.1FB50244-4098-4980-B853-C122E7C6ECD8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).